Gene-level copy-number profile of tumor specimen TCGA-98-8021-01A from TCGA case TCGA-98-8021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,738 days).
Specimen TCGA-98-8021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.19a673ab-b979-4e66-947f-e8cfca9b9448.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-8021-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a092eb18-3f4b-44ee-b94f-2b0f009f8ea5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,749; copy number 2: 34,497; copy number 3: 4,440; copy number 4: 125; copy number 5: 851; copy number 6: 864; copy number 7: 61; copy number 8: 81; copy number 9: 73; copy number 10: 25; copy number 11: 37; copy number 20: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-8021-01A-11D-2243-01): tumor purity 0.41, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,004 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–39,487,177, 1 gene, copy number 8 (within-gene range 2–8): MACF1.
- chr1:39,249,838–41,383,590, 80 genes, copy number 8 (broad region; genes not listed).
- chr1:48,222,685–50,023,954, 18 genes, copy number 6 (within-gene range 3–6): SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1, AGBL4, AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P.
- chr1:117,929,720–119,896,515, 42 genes, copy number 5: WDR3, SPAG17, AL391557.1, RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30.
- chr3:115,147,605–115,564,389, 1 gene, copy number 5 (within-gene range 3–5): AC026341.1.
- chr3:115,413,476–198,222,513, 1,495 genes, copy number 5–6 (broad region; genes not listed).
- chr6:106,271,634–107,958,208, 31 genes, copy number 5–10 (within-gene range 2–10): U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50.
- chr8:36,308,245–43,674,591, 182 genes, copy number 6–9 (broad region; genes not listed).
- chr20:1,947,246–4,015,558, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:7,146,467–13,638,932, 77 genes, copy number 5–20 (within-gene range 3–20) (broad region; genes not listed).
- chr20:15,892,355–16,573,448, 4 genes, copy number 5 (within-gene range 3–5): AL079338.1, AL161941.1, PPIAP17, KIF16B.

Autosomal genes at a single copy (total copy number 1): 18,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
